Somatic mutation profile of tumor specimen TCGA-41-3392-01A (aliquot TCGA-41-3392-01A-01D-1495-08) from TCGA case TCGA-41-3392, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 88.6 years (32,351 days).
Specimen TCGA-41-3392-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 369cd3db-918b-4cb1-9727-a273540c45d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-41-3392-10A (Blood Derived Normal), aliquot TCGA-41-3392-10A-01D-1495-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c99ec1f7-f635-4de5-8abc-8d7a790f6944

The open-access MAF lists 71 somatic variants for this specimen: 51 protein-altering or splice-affecting, 16 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 16, Intron 3, Nonsense Mutation 2, Frame Shift Del 2, RNA 1, Frame Shift Ins 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACOT4 | c.332G>A p.G111D | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.818); catalogued as COSV58335370; called by muse, mutect2
- ADAM20 | c.1960T>A p.C654S | Missense Mutation (SNP) | VAF 157/481 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56454074; called by muse, mutect2, varscan2
- AHCYL2 | c.875G>A p.C292Y | Missense Mutation (SNP) | VAF 55/303 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV61485104; called by muse, mutect2, varscan2
- ARIH2 | c.241G>T p.A81S | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62703841; called by muse, mutect2, varscan2
- B4GALNT1 | c.1555C>T p.R519W | Missense Mutation (SNP) | VAF 79/211 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.692); catalogued as rs755171392, COSV57541201, COSV57544389; called by muse, mutect2, varscan2
- CABIN1 | c.374A>G p.N125S | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV54077553; called by muse, mutect2, varscan2
- CALCOCO1 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.92); catalogued as rs747890587, COSV50411648; called by muse, mutect2, varscan2
- CD164 | c.560G>T p.C187F | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51532814; called by muse, mutect2, varscan2
- CD6 | c.1960C>G p.P654A | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV57835883; called by muse, mutect2, varscan2
- CLYBL | c.248A>C p.K83T | Missense Mutation (SNP) | VAF 66/118 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59216960; called by muse, mutect2, varscan2
- CPEB2 | c.2584G>A p.D862N | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (1); catalogued as COSV52589266, COSV52590054; called by muse, mutect2, varscan2
- DNAH5 | c.2743G>A p.A915T | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV54203979; called by muse, mutect2, varscan2
- DPP6 | c.944A>G p.Y315C (on ENST00000377770 / NM_001364500.2; = p.Y253C on NM_001936.5) | Missense Mutation (SNP) | VAF 14/191 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59597959; called by muse, mutect2
- DYNC1I1 | c.1321G>A p.A441T | Missense Mutation (SNP) | VAF 70/451 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.59); catalogued as rs375862083, COSV61455759; called by muse, mutect2, varscan2
- FECH | c.611A>G p.N204S | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV50490264; called by muse, mutect2, varscan2
- GABRA4 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT tolerated (0.58); PolyPhen benign (0.013); catalogued as COSV51922515; called by muse, mutect2, varscan2
- HECTD4 | c.10900G>C p.V3634L | Missense Mutation (SNP) | VAF 105/297 reads (35%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.429); catalogued as COSV66386671; called by muse, mutect2, varscan2
- HPSE2 | c.1408C>A p.P470T | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV65180536; called by muse, mutect2, varscan2
- IGHA2 | c.259G>A p.V87M | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs782591503; called by muse, mutect2, varscan2
- IRF6 | c.916G>A p.V306I | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT tolerated (0.69); PolyPhen benign (0.177); catalogued as COSV65418679, COSV65419039; called by muse, mutect2, varscan2
- KCNA7 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.149); catalogued as rs541248038, COSV55502864; called by muse, mutect2, varscan2
- KRTAP10-1 | c.553G>A p.V185M | Missense Mutation (SNP) | VAF 69/208 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.806); catalogued as rs782319981, COSV59951733; called by muse, mutect2, varscan2
- MAS1L | c.377C>T p.S126L | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1195512003, COSV101009734, COSV65808454; called by muse, mutect2, varscan2
- MORN5 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs751585952, COSV65648473; called by muse, mutect2, varscan2
- MUC4 | c.2387G>A p.R796Q | Missense Mutation (SNP) | VAF 62/154 reads (40%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.234); catalogued as rs755686884, COSV62129304; called by muse, mutect2, varscan2
- NBAS | c.1211C>T p.A404V | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV55712590; called by muse, mutect2
- NEB | c.528G>A p.W176* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as COSV50810032, COSV51468789; called by muse, mutect2, varscan2
- OR2T12 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 56/109 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.052); catalogued as rs200352170, COSV58776065, COSV58778849; called by muse, mutect2, varscan2
- OR5B17 | c.391A>G p.T131A | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.02); catalogued as COSV62159855; called by muse, mutect2, varscan2
- OR6C4 | c.581A>G p.E194G | Missense Mutation (SNP) | VAF 57/163 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.17); catalogued as COSV67792759; called by muse, mutect2, varscan2
- PCDHA1 | c.214A>G p.R72G | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs782682818, COSV65372651; called by muse, mutect2
- PCDHA13 | c.1985C>T p.T662M | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.966); catalogued as rs1356283866, COSV56477666, COSV99170418; called by muse, mutect2, varscan2
- PHLDA1 | c.1109C>T p.P370L | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.058); catalogued as rs1399530760, COSV56996706; called by muse, mutect2, varscan2
- PHLPP2 | c.2468G>A p.R823Q | Missense Mutation (SNP) | VAF 126/259 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as rs752054132, COSV62422513; called by muse, mutect2, varscan2
- PLCL2 | c.1573A>T p.I525F (on ENST00000615277 / NM_001144382.2; = p.I399F on NM_015184.5) | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.222); catalogued as COSV67620502; called by muse, mutect2, varscan2
- PLIN4 | c.2714C>A p.T905N (on ENST00000301286; = p.T920N on NM_001367868.2) | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as rs746541245, COSV56686791; called by muse, mutect2, varscan2
- PPP1R12C | c.2160+1G>C p.X720_splice | Splice Site (SNP) | VAF 2/12 reads (17%) | catalogued as COSV52379967; called by muse, mutect2
- PTPRT | c.1357C>T p.R453C | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.772); catalogued as rs1371429276, COSV61960613; called by muse, mutect2, varscan2
- RASGRF1 | c.2483C>T p.A828V | Missense Mutation (SNP) | VAF 49/97 reads (51%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs745726848, COSV67249261; called by muse, mutect2, varscan2
- REN | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as rs191049685, COSV65817317; called by muse, mutect2, varscan2
- ROS1 | c.3059del p.P1020Lfs*60 | Frame Shift Del (DEL) | VAF 12/76 reads (16%) | catalogued as COSV100877845, COSV63862424; called by mutect2, pindel, varscan2
- RPL13A | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as COSV52618205; called by muse, mutect2
- SH3TC1 | c.2977T>A p.C993S | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as COSV55281156; called by muse, mutect2, varscan2
- SLC13A3 | c.1229C>G p.T410R | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.614); catalogued as COSV51711817; called by muse, mutect2, varscan2
- TNFSF10 | c.22G>T p.G8W | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.782); catalogued as COSV53842463; called by muse, mutect2, varscan2
- TTC31 | c.91C>T p.L31F | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.063); catalogued as rs753089585, COSV51776081; called by muse, mutect2
- UBE4B | c.3139C>T p.R1047* (on ENST00000343090 / NM_001105562.3; = p.R918* on NM_006048.5) | Nonsense Mutation (SNP) | VAF 36/125 reads (29%) | catalogued as COSV53527127; called by muse, mutect2, varscan2
- WDR92 | c.1042G>C p.V348L | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV54560424; called by muse, mutect2
- HERC2 | c.1287dup p.L430Vfs*49 | Frame Shift Ins (INS) | VAF 42/70 reads (60%) | called by mutect2, pindel, varscan2
- LFNG | c.408del p.W137Gfs*8 | Frame Shift Del (DEL) | VAF 19/62 reads (31%) | called by mutect2, pindel, varscan2
- NF1 | c.1780_1803del p.T594_R601del | In Frame Del (DEL) | VAF 15/96 reads (16%) | called by mutect2, pindel
- ADARB2 | c.1548C>T p.R516= | Silent (SNP) | VAF 9/13 reads (69%) | catalogued as rs772506968, COSV67214797; called by muse, mutect2, varscan2
- BAIAP2 | c.1413C>T p.Y471= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as rs375290881; called by muse, mutect2, varscan2
- CACNA1S | c.1533C>A p.I511= | Silent (SNP) | VAF 24/89 reads (27%) | catalogued as rs780112076, COSV100754821, COSV99054157; called by muse, mutect2, varscan2
- CD14 | c.339A>T p.L113= | Silent (SNP) | VAF 31/84 reads (37%) | catalogued as COSV57369814; called by muse, mutect2, varscan2
- CDH15 | c.1050G>A p.A350= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs548832046, COSV57021934; called by muse, mutect2, varscan2
- CYP4F8 | c.318C>T p.I106= | Silent (SNP) | VAF 77/184 reads (42%) | catalogued as rs375063511, COSV100358293; called by muse, mutect2, varscan2
- GJA8 | c.129C>T p.F43= | Silent (SNP) | VAF 60/120 reads (50%) | catalogued as rs267598000, COSV53787764; called by muse, mutect2, varscan2
- HOXC11 | c.810C>T p.N270= | Silent (SNP) | VAF 38/104 reads (37%) | catalogued as COSV54532267; called by muse, mutect2, varscan2
- OR11G2 | c.195C>G p.L65= | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as COSV62131753; called by muse, mutect2, varscan2
- RASSF5 | c.1131T>G p.L377= | Silent (SNP) | VAF 46/239 reads (19%) | catalogued as COSV55112032; called by muse, mutect2, varscan2
- ROBO2 | c.93G>A p.P31= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs199878362, COSV59896816; called by muse, mutect2, varscan2
- SEC22C | c.480G>C p.V160= | Silent (SNP) | VAF 66/151 reads (44%) | catalogued as COSV52564342; called by muse, mutect2, varscan2
- SLC10A4 | c.1029C>T p.L343= | Silent (SNP) | VAF 84/220 reads (38%) | catalogued as COSV56718068; called by muse, mutect2, varscan2
- SLIT3 | c.2382C>A p.T794= | Silent (SNP) | VAF 41/169 reads (24%) | catalogued as COSV60592630, COSV60597457; called by muse, mutect2, varscan2
- SLITRK4 | c.45G>A p.S15= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as rs782432373, COSV62022127; called by muse, mutect2, varscan2
- TADA3 | c.951C>T p.R317= | Silent (SNP) | VAF 36/77 reads (47%) | catalogued as COSV57332472; called by muse, mutect2, varscan2
- C2orf83 | n.358A>T | RNA (SNP) | VAF 12/115 reads (10%) | catalogued as COSV52310655; called by muse, mutect2, varscan2
- F2R | c.88+297C>T | Intron (SNP) | VAF 12/23 reads (52%) | catalogued as rs773170045, COSV59930549; called by muse, varscan2
- LY9 | c.454+1821G>A | Intron (SNP) | VAF 61/126 reads (48%) | catalogued as rs775837935, COSV54433610; called by muse, mutect2, varscan2
- TTN | c.10361-4069G>A | Intron (SNP) | VAF 15/299 reads (5%) | catalogued as COSV59887220; called by muse, mutect2
